Somatic mutation profile of tumor specimen ALCH-B2O1-TTP1-B (aliquot ALCH-B2O1-TTP1-B-1-0-D-A777-36) from ALCHEMIST case ALCH-B2O1, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 42.3 years (15,454 days).
Specimen ALCH-B2O1-TTP1-B: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 646f1b8e-0280-4339-99ce-f9b1599ae2b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2O1-NB1-A (Blood Derived Normal), aliquot ALCH-B2O1-NB1-A-1-0-D-A777-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2d6c9b1-ac7e-4dab-b053-98a222bf85f6

The open-access MAF lists 18 somatic variants for this specimen: 12 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 5, Nonsense Mutation 1, In Frame Del 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2239_2256del p.L747_S752del | In Frame Del (DEL) | VAF 58/472 reads (12%) | hotspot (GDC flag); catalogued as rs121913440, COSV51767308, COSV51778874; ClinVar: drug response; called by mutect2, pindel
- ADGRL3 | c.1022G>A p.W341* (on ENST00000506720 / NM_001322402.2; = p.W273* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 14/338 reads (4%) | catalogued as COSV72266888; called by muse, mutect2
- MAP2K3 | c.107C>A p.P36H (on ENST00000342679 / NM_145109.3; = p.P7H on NM_002756.4) | Missense Mutation (SNP) | VAF 24/364 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV57565769, COSV57569555; called by muse, mutect2
- VGLL3 | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 10/303 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1207532656, COSV101052022; called by muse, mutect2
- BEND5 | c.463T>A p.C155S | Missense Mutation (SNP) | VAF 41/348 reads (12%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- BOD1L1 | c.4730G>T p.G1577V | Missense Mutation (SNP) | VAF 8/137 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2
- CDHR3 | c.942A>C p.E314D | Missense Mutation (SNP) | VAF 27/249 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- KMT2C | c.6707C>A p.S2236Y | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2
- SERINC3 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 16/318 reads (5%) | SIFT tolerated (0.66); PolyPhen benign (0.015); called by muse, mutect2
- SLCO2A1 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 14/163 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- WEE1 | c.158C>G p.S53W | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); called by muse, varscan2
- ZNF729 | c.2682del p.K894Nfs*7 | Frame Shift Del (DEL) | VAF 53/295 reads (18%) | called by mutect2, pindel, varscan2
- ART3 | c.153C>T p.Y51= | Silent (SNP) | VAF 18/254 reads (7%) | catalogued as rs746724267, COSV61914566; called by muse, mutect2
- BPIFB4 | c.774C>T p.N258= | Silent (SNP) | VAF 16/140 reads (11%) | catalogued as rs1488689709; called by muse, mutect2, varscan2
- GABRB3 | c.354G>A p.V118= | Silent (SNP) | VAF 19/281 reads (7%) | called by muse, mutect2
- KIAA0586 | c.1047G>A p.L349= (on ENST00000619416 / NM_001244190.2; = p.L364= on NM_014749.5) | Silent (SNP) | VAF 27/208 reads (13%) | called by muse, mutect2, varscan2
- ST6GALNAC3 | c.699C>T p.H233= | Silent (SNP) | VAF 28/202 reads (14%) | catalogued as rs1212420117, COSV60321071; called by muse, mutect2, varscan2
- TP53 | c.993+312C>G | Intron (SNP) | VAF 51/266 reads (19%) | catalogued as COSV52819048, COSV52956881; called by muse, mutect2, varscan2
